Somatic mutation profile of tumor specimen TCGA-O2-A52Q-01A (aliquot TCGA-O2-A52Q-01A-11D-A26M-08) from TCGA case TCGA-O2-A52Q, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage III; Age at diagnosis: 45.0 years (16,429 days).
Specimen TCGA-O2-A52Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 054b8fbd-e8bb-44ca-9b88-87409f4c750a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O2-A52Q-10A (Blood Derived Normal), aliquot TCGA-O2-A52Q-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40290f45-7b9f-49f8-bfd8-df829f871503

The open-access MAF lists 1,061 somatic variants for this specimen: 816 protein-altering or splice-affecting, 220 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 695, Silent 220, Nonsense Mutation 63, Splice Site 23, Frame Shift Del 17, Intron 13, Frame Shift Ins 11, RNA 7, Splice Region 5, In Frame Del 2, 3'UTR 2, 5'Flank 1.

Variants (750 of 1,061; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99256422; called by muse, mutect2, varscan2
- AAGAB | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99971923; called by muse, mutect2, varscan2
- ABCA13 | c.9681G>T p.Q3227H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101446977; called by muse, mutect2, varscan2
- ABCB1 | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); catalogued as COSV99713148; called by muse, mutect2, varscan2
- ABCD2 | c.2064G>T p.L688F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100429514; called by muse, mutect2, varscan2
- ABCD3 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1244574221, COSV100238917; called by muse, mutect2, varscan2
- ACAN | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100718199; called by muse, mutect2, varscan2
- ACAP1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs974930990, COSV99341692; called by muse, mutect2, varscan2
- ACHE | c.911T>A p.L304H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99574163; called by muse, mutect2, varscan2
- ACSBG1 | c.1449C>A p.H483Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs1481804946, COSV99357436; called by muse, mutect2, varscan2
- ACSS3 | c.1992C>A p.Y664* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99698898; called by muse, mutect2
- ACTN2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.833); catalogued as rs758358941, COSV63973008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1B | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100008107; called by muse, mutect2
- ADAM19 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57424132, COSV99977381; called by muse, mutect2
- ADAM23 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as rs906990188, COSV100007738; called by muse, mutect2, varscan2
- ADAMTS15 | c.2758T>A p.C920S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143411; called by muse, mutect2, varscan2
- ADAMTS16 | c.2410G>T p.D804Y | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57003456, COSV57011657; called by muse, mutect2
- ADAMTS5 | c.1503C>A p.F501L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs770985728, COSV99537673; called by muse, mutect2, varscan2
- ADCY2 | c.240A>G p.I80M | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100602990; called by muse, mutect2, varscan2
- ADCY4 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1399184282, COSV100156599; called by muse, mutect2, varscan2
- ADCY8 | c.2939C>A p.A980D | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.474); catalogued as COSV99652514; called by muse, mutect2, varscan2
- ADD2 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781934029, COSV52472542; called by muse, mutect2, varscan2
- ADGRA3 | c.3539G>T p.R1180L | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99293333; called by muse, mutect2, varscan2
- ADGRE2 | c.1670C>A p.T557N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100216082; called by muse, mutect2, varscan2
- ADGRE3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV53734416; called by muse, mutect2, varscan2
- ADGRL4 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100876032; called by muse, mutect2, varscan2
- AFF2 | c.2624C>A p.T875K | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.129); catalogued as COSV99664224; called by muse, mutect2, varscan2
- AGL | c.2308+1G>T p.X770_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99649334; called by muse, mutect2, varscan2
- AHNAK2 | c.13741G>T p.E4581* | Nonsense Mutation (SNP) | VAF 76/273 reads (28%) | catalogued as COSV100317648; called by muse, mutect2, varscan2
- AHNAK2 | c.12637A>T p.K4213* | Nonsense Mutation (SNP) | VAF 90/282 reads (32%) | catalogued as COSV100317650; called by muse, mutect2, varscan2
- AIM2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100931079; called by muse, mutect2, varscan2
- AL592490.1 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.311); catalogued as rs758897549, COSV101308209; called by muse, mutect2, varscan2
- ALG6 | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673225; called by muse, mutect2, varscan2
- AMER3 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366605; called by muse, mutect2, varscan2
- AMOTL1 | c.2537T>A p.L846Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.854); catalogued as COSV100504448; called by muse, mutect2, varscan2
- ANGEL1 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200406, COSV99200499; called by muse, mutect2, varscan2
- ANGEL1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99200409; called by muse, mutect2, varscan2
- ANKS1B | c.3446T>A p.I1149N (on ENST00000547776 / NM_152788.4; = p.I315N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100228032; called by muse, mutect2, varscan2
- AOC2 | c.1646G>T p.W549L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99520172; called by muse, mutect2, varscan2
- AOX1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101022006; called by muse, mutect2, varscan2
- AP002512.3 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV99687974; called by muse, mutect2
- APOO | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101004901; called by muse, mutect2, varscan2
- ARAP3 | c.2650C>A p.Q884K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99499756; called by muse, mutect2, varscan2
- AREL1 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV100707615; called by muse, mutect2, varscan2
- ARHGAP15 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV99711056; called by muse, mutect2, varscan2
- ARHGAP32 | c.4750C>T p.Q1584* (on ENST00000310343 / NM_001378025.1; = p.Q1235* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100087956; called by muse, mutect2, varscan2
- ARHGEF11 | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100168652; called by muse, mutect2, varscan2
- ARHGEF25 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99677997; called by muse, varscan2
- ARID2 | c.2788A>G p.S930G | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV100536286; called by muse, mutect2
- ARID5B | c.1205T>A p.I402N | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99689740; called by muse, mutect2
- ARMC3 | c.2468C>A p.A823E | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs867516472, COSV53067705, COSV99957550; called by muse, mutect2, varscan2
- ARSK | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100706660; called by muse, mutect2
- ASAP3 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV60873107; called by muse, mutect2, varscan2
- ASB14 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); catalogued as COSV101274148; called by muse, mutect2, varscan2
- ASIC5 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101539752; called by muse, mutect2, varscan2
- ASXL3 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.988); catalogued as rs764330971, COSV99325078; called by muse, mutect2, varscan2
- ASXL3 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV99325082; called by muse, mutect2, varscan2
- ATAD2 | c.3429G>C p.Q1143H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54881624, COSV99784747; called by muse, mutect2, varscan2
- ATG2B | c.4443G>T p.M1481I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1220864469, COSV99952079; called by muse, mutect2, varscan2
- ATM | c.6829C>T p.Q2277* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as CM0910515, COSV99589793; called by muse, mutect2, varscan2
- ATP10B | c.3024G>T p.Q1008H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.985); catalogued as COSV59150905; called by muse, mutect2, varscan2
- ATP10B | c.2936C>A p.P979H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100515093; called by muse, mutect2, varscan2
- ATP1A3 | c.611C>G p.A204G (on ENST00000545399 / NM_001256214.2; = p.A191G on NM_152296.5) | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100132281; called by muse, mutect2, varscan2
- ATP2A2 | c.2032G>T p.V678F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100428629; called by muse, mutect2, varscan2
- ATRNL1 | c.4078G>C p.D1360H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100370875; called by muse, mutect2, varscan2
- B4GALT2 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); catalogued as COSV99356472; called by muse, mutect2, varscan2
- BAAT | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99408515; called by muse, mutect2, varscan2
- BBS5 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV99751962; called by muse, mutect2, varscan2
- BCAS3 | c.1973+1G>T p.X658_splice (on ENST00000390652 / NM_001353144.2; = p.X643_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV101176003; called by muse, mutect2, varscan2
- BICDL1 | c.1247G>C p.R416P | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs199508010, COSV57494091, COSV99985839; called by muse, mutect2, varscan2
- BRD7 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV54268645, COSV99576049; called by muse, mutect2, varscan2
- BRDT | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.27); catalogued as COSV100746392; called by muse, mutect2, varscan2
- BRINP2 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100838106; called by muse, mutect2, varscan2
- BRMS1 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1027722053, COSV100240280, COSV60820198; called by muse, mutect2, varscan2
- BROX | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.378); catalogued as rs376837737; called by muse, mutect2, varscan2
- BRSK1 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.349); catalogued as COSV100510632; called by muse, mutect2, varscan2
- BRWD3 | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100956113; called by muse, mutect2, varscan2
- BTBD11 | c.2095G>C p.G699R (on ENST00000280758 / NM_001018072.2; = p.G236R on NM_001017523.2) | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99775950; called by muse, mutect2, varscan2
- BTN3A2 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 120/222 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100709661; called by muse, mutect2, varscan2
- BUB3 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100378772; called by muse, mutect2, varscan2
- C1QL1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs761519417, COSV99492764; called by muse, mutect2, varscan2
- C1orf141 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100924345; called by muse, mutect2, varscan2
- C1orf35 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99683226; called by muse, mutect2, varscan2
- C1orf87 | c.1076T>A p.L359Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100967092; called by muse, mutect2, varscan2
- C21orf62 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212312; called by muse, mutect2
- C2CD3 | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486777; called by muse, mutect2, varscan2
- CABYR | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1430228115, COSV100510071; called by muse, mutect2, varscan2
- CACHD1 | c.3157G>T p.D1053Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99262406; called by muse, mutect2, varscan2
- CACNA2D1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100666712; called by muse, mutect2, varscan2
- CACNG5 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50055699, COSV50057188; called by muse, mutect2, varscan2
- CADM1 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522786, COSV59024225; called by muse, mutect2, varscan2
- CADPS | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99338527; called by muse, mutect2, varscan2
- CALCOCO1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100017354; called by muse, mutect2, varscan2
- CALCRL | c.875A>T p.Y292F | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV101130969, COSV66475848; called by muse, mutect2, varscan2
- CAMK1G | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99151698; called by muse, mutect2, varscan2
- CARD10 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99324992, COSV99325435; called by muse, mutect2, varscan2
- CBLB | c.2297-2A>G p.X766_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as rs959524273, COSV99913520; called by muse, mutect2, varscan2
- CBLN4 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99290562; called by muse, mutect2, varscan2
- CBY2 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100137624, COSV60119799; called by muse, mutect2, varscan2
- CCDC70 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV54430760, COSV99665367; called by muse, mutect2, varscan2
- CCDC80 | c.2172G>A p.K724= | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as rs763561315, COSV99244838; called by muse, mutect2, varscan2
- CCDC88C | c.3613G>T p.E1205* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101105690; called by muse, varscan2
- CCDC97 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 58/101 reads (57%) | catalogued as COSV99523752; called by muse, mutect2, varscan2
- CCER1 | c.207A>T p.Q69H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100727047; called by muse, mutect2, varscan2
- CCL7 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99565568; called by muse, mutect2, varscan2
- CCND3 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026811; called by muse, mutect2, varscan2
- CCR10 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52849340; called by muse, mutect2, varscan2
- CCR3 | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs756281359, COSV100656543, COSV62462751; called by muse, mutect2, varscan2
- CCR4 | c.260T>A p.L87H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447409; called by muse, mutect2, varscan2
- CD244 | c.436C>A p.L146M (on ENST00000368033 / NM_001166663.2; = p.L141M on NM_016382.4) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV100458579; called by muse, mutect2, varscan2
- CD72 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99427475; called by muse, mutect2, varscan2
- CD84 | c.88A>T p.N30Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV100246043; called by muse, mutect2, varscan2
- CDC45 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99596740; called by muse, mutect2, varscan2
- CDCP2 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100313491; called by muse, mutect2, varscan2
- CDH10 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.061); catalogued as COSV100051675; called by muse, mutect2, varscan2
- CDH13 | c.1763C>A p.T588K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as rs530695746, COSV99226590; called by muse, mutect2, varscan2
- CDH18 | c.579C>A p.N193K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1396808942, COSV56917732; called by muse, mutect2, varscan2
- CDH23 | c.6667C>A p.L2223M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as CD154046, COSV99821199; called by muse, mutect2, varscan2
- CDH4 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100848993; called by muse, mutect2, varscan2
- CDH4 | c.1941C>G p.Y647* | Nonsense Mutation (SNP) | VAF 75/217 reads (35%) | catalogued as COSV64645345, COSV64665328; called by muse, mutect2, varscan2
- CDH7 | c.2188C>A p.L730M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59883998; called by muse, mutect2, varscan2
- CDH9 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV50365069; called by muse, mutect2, varscan2
- CDON | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.395); catalogued as rs986863818, COSV99701435; called by muse, mutect2, varscan2
- CECR2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV99378081; called by muse, mutect2, varscan2
- CEP170B | c.3053C>T p.P1018L (on ENST00000453495; = p.P947L on NM_015005.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs756896563, COSV69026626; called by muse, mutect2
- CEP250 | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100698946; called by muse, mutect2, varscan2
- CFHR5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV56826134; called by muse, mutect2, varscan2
- CFTR | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.604); catalogued as rs150239014, CD941997; called by muse, mutect2, varscan2
- CHD3 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100391241; called by muse, mutect2, varscan2
- CHD9 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV101272140; called by muse, mutect2
- CHRM4 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 105/177 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as COSV100708803; called by muse, mutect2, varscan2
- CIAPIN1 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101275893; called by muse, mutect2, varscan2
- CLASP2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100223513; called by muse, mutect2, varscan2
- CLCN4 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101073846; called by muse, mutect2, varscan2
- CLDN17 | c.192C>A p.C64* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99729222; called by muse, mutect2, varscan2
- CLDN19 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs1033106967, COSV56418508; called by muse, mutect2, varscan2
- CLNK | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1455938088, COSV57014686, COSV99904403; called by muse, mutect2, varscan2
- CMTR2 | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as COSV100579176; called by muse, mutect2, varscan2
- CNTNAP3 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99904890; called by muse, mutect2, varscan2
- CNTNAP5 | c.1207C>A p.L403M | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101443616; called by muse, mutect2, varscan2
- COL11A1 | c.3048C>G p.I1016M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100616751; called by muse, mutect2, varscan2
- COL15A1 | c.3728C>A p.A1243D | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as COSV100897740; called by muse, mutect2, varscan2
- COL19A1 | c.2668-1G>T p.X890_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100506393; called by muse, mutect2, varscan2
- COL27A1 | c.134-2A>T p.X45_splice | Splice Site (SNP) | VAF 65/151 reads (43%) | catalogued as COSV100621032; called by muse, mutect2, varscan2
- COL28A1 | c.2690_2691insG p.V898Sfs*7 | Frame Shift Ins (INS) | VAF 21/58 reads (36%) | catalogued as COSV101258629; called by mutect2, pindel, varscan2
- COL3A1 | c.1960G>T p.G654* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100483091, COSV100483638; called by muse, mutect2, varscan2
- COL3A1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM1412562, COSV100483093; called by muse, mutect2, varscan2
- COL4A5 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100087899; called by muse, mutect2, varscan2
- COL4A5 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100087900; called by muse, mutect2, varscan2
- COL6A3 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as COSV99798527; called by muse, mutect2, varscan2
- COLEC11 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as COSV99363298; called by muse, mutect2, varscan2
- CPEB4 | c.1241G>C p.S414T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV99437198; called by muse, mutect2, varscan2
- CPXM2 | c.1704G>T p.R568S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV99582377; called by muse, mutect2, varscan2
- CR1 | c.5878C>A p.P1960T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100887635; called by muse, mutect2, varscan2
- CRB1 | c.849-1G>T p.X283_splice | Splice Site (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100959172, COSV66347542; called by muse, mutect2, varscan2
- CRHR1 | c.601G>T p.V201F (on ENST00000398285 / NM_001145146.2; = p.V172F on NM_004382.5) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV99523681; called by muse, mutect2, varscan2
- CRIM1 | c.2512A>T p.T838S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99753482; called by muse, mutect2, varscan2
- CRNKL1 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV100131663, COSV58548132; called by muse, mutect2, varscan2
- CRYL1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.979); catalogued as rs756024227, COSV53415832; called by muse, mutect2, varscan2
- CSMD3 | c.10175C>A p.T3392N (on ENST00000297405 / NM_001363185.1; = p.T3223N on NM_052900.3) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99835639; called by muse, mutect2, varscan2
- CSMD3 | c.9827A>G p.N3276S (on ENST00000297405 / NM_001363185.1; = p.N3107S on NM_052900.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99835642; called by muse, varscan2
- CSMD3 | c.9781C>A p.P3261T (on ENST00000297405 / NM_001363185.1; = p.P3092T on NM_052900.3) | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as COSV52261171, COSV99835644; called by muse, varscan2
- CSMD3 | c.5180G>T p.C1727F (on ENST00000297405 / NM_001363185.1; = p.C1623F on NM_052900.3) | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99835646; called by muse, mutect2, varscan2
- CSPP1 | c.1484C>T p.P495L (on ENST00000676605; = p.P454L on NM_024790.6) | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99138621; called by muse, mutect2, varscan2
- CTNNA2 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100784490; called by muse, mutect2
- CTNNA2 | c.1381C>A p.Q461K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58138714; called by muse, mutect2, varscan2
- CTSB | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100565889; called by muse, mutect2, varscan2
- CWC22 | c.1603A>T p.T535S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99844314; called by muse, mutect2, varscan2
- CWC27 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV101126509; called by muse, mutect2, varscan2
- CYLC1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs751696972, COSV100254717; called by muse, mutect2, varscan2
- CYLC2 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV100872459; called by muse, mutect2, varscan2
- CYP21A2 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as rs1185350916, COSV100926378; ClinVar: uncertain significance; called by muse, mutect2
- CYP2C8 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100987948; called by muse, mutect2, varscan2
- CYP2J2 | c.1491C>A p.C497* | Nonsense Mutation (SNP) | VAF 149/596 reads (25%) | catalogued as COSV100968038; called by muse, mutect2, varscan2
- CYP4A11 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100152069, COSV100152413; called by muse, mutect2, varscan2
- DACH2 | c.1474T>G p.Y492D | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100913327; called by muse, mutect2, varscan2
- DBF4 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV99719338; called by muse, mutect2, varscan2
- DCAF4L2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765137281, COSV100150640, COSV100150926; called by muse, varscan2
- DCDC1 | c.2638C>A p.H880N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100338323; called by muse, mutect2, varscan2
- DCLK1 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55174599, COSV55205136; called by muse, mutect2, varscan2
- DECR1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as rs140706902; called by muse, varscan2
- DENND2C | c.1910G>A p.G637E (on ENST00000393274 / NM_001256404.2; = p.G580E on NM_198459.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283935; called by muse, mutect2, varscan2
- DENND4C | c.5105G>C p.R1702P (on ENST00000434457 / NM_001330640.2; = p.R1653P on NM_017925.7) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100727451; called by muse, mutect2, varscan2
- DGKB | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV51783350, COSV99339929; called by muse, mutect2
- DGKI | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV99934851; called by muse, mutect2, varscan2
- DISP3 | c.2677C>G p.L893V | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as COSV99608763; called by muse, mutect2, varscan2
- DLGAP3 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99332749; called by muse, mutect2, varscan2
- DNAH10 | c.5997C>A p.Y1999* (on ENST00000409039; = p.Y1938* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV101292294; called by muse, mutect2, varscan2
- DNAH11 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100179382; called by muse, mutect2, varscan2
- DNAH2 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.12); catalogued as COSV99318224; called by muse, mutect2, varscan2
- DNAH5 | c.5596C>G p.L1866V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV99450264; called by muse, mutect2, varscan2
- DNAJC22 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101222542; called by muse, mutect2, varscan2
- DNAJC25 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100543376; called by muse, mutect2, varscan2
- DOCK2 | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56951037; called by muse, mutect2, varscan2
- DOCK3 | c.5890C>A p.P1964T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.202); catalogued as COSV99812404; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPP10 | c.2378A>T p.E793V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100064212, COSV100066254; called by muse, mutect2, varscan2
- DPP4 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100858892; called by muse, mutect2, varscan2
- DPPA2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV101524769, COSV72118346; called by muse, mutect2, varscan2
- DRD2 | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100669703; called by muse, mutect2, varscan2
- DSG3 | c.2697G>T p.Q899H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.854); catalogued as COSV99934215; called by muse, mutect2, varscan2
- DTWD2 | c.448A>C p.I150L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.049); catalogued as COSV100406994; called by muse, mutect2, varscan2
- DTX3L | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99950044; called by muse, mutect2, varscan2
- DYNC1H1 | c.5535C>G p.Y1845* | Nonsense Mutation (SNP) | VAF 41/135 reads (30%) | catalogued as COSV100794951; called by muse, mutect2, varscan2
- DYSF | c.2285A>G p.H762R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV99244524; called by muse, mutect2, varscan2
- DYSF | c.3454T>A p.Y1152N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749405808, COSV99247462; called by muse, mutect2, varscan2
- DZANK1 | c.1265G>T p.R422I (on ENST00000262547 / NM_001099407.1; = p.R229I on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99362512; called by muse, mutect2, varscan2
- DZIP3 | c.2838G>T p.L946F | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100847809; called by muse, mutect2, varscan2
- EBF1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV100565852, COSV58186604; called by muse, mutect2, varscan2
- EDA2R | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99490701; called by muse, mutect2
- EDEM2 | c.365-2A>G p.X122_splice | Splice Site (SNP) | VAF 120/301 reads (40%) | catalogued as COSV100993758; called by muse, mutect2, varscan2
- EDIL3 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV99674410; called by muse, mutect2, varscan2
- EDIL3 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV56883404, COSV99676869; called by muse, mutect2
- EEA1 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467722; called by muse, mutect2, varscan2
- EFR3A | c.1592A>G p.Y531C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV99603034; called by muse, mutect2, varscan2
- EHD2 | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99621975; called by muse, mutect2, varscan2
- ELAPOR2 | c.1132G>T p.E378* (on ENST00000450689 / NM_001142749.3; = p.E211* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as COSV99788844; called by muse, mutect2, varscan2
- ELF3 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV62838350, COSV62839393; called by muse, mutect2, varscan2
- ELMO3 | c.1426G>C p.E476Q (on ENST00000652269; = p.E423Q on NM_024712.5) | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58527496; called by muse, mutect2, varscan2
- EMID1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); catalogued as COSV100469018; called by muse, mutect2, varscan2
- ENOPH1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99908692; called by muse, mutect2, varscan2
- EP300 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 37/239 reads (15%) | catalogued as COSV99608663; called by muse, mutect2, varscan2
- EPHB3 | c.1945C>A p.R649S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.8); PolyPhen probably damaging (1); catalogued as COSV100382860, COSV100383095; called by muse, mutect2, varscan2
- EPS8L3 | c.1730G>A p.R577Q (on ENST00000361965 / NM_133181.4; = p.R547Q on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as rs577159080, COSV62609165; called by muse, mutect2, varscan2
- ERBB4 | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99624550; called by muse, mutect2, varscan2
- ERN1 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV101458449; called by muse, mutect2, varscan2
- ESCO1 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99332308; called by muse, mutect2
- ESPL1 | c.2828A>G p.H943R | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV99229373; called by muse, mutect2, varscan2
- EXOC4 | c.979dup p.E327Gfs*21 | Frame Shift Ins (INS) | VAF 9/82 reads (11%) | catalogued as rs1563033105; called by mutect2, pindel, varscan2
- EXOC6 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as COSV99591986; called by muse, mutect2
- EXTL3 | c.2487C>G p.I829M | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV55040563; called by muse, mutect2, varscan2
- F2R | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100058478, COSV59930063; called by muse, mutect2, varscan2
- FAAH | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99680090; called by muse, mutect2, varscan2
- FAAP24 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs773972293, COSV54282713; called by muse, mutect2, varscan2
- FAM220A | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV57627109; called by muse, mutect2, varscan2
- FAM83B | c.980A>T p.D327V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100174519; called by muse, mutect2, varscan2
- FAT3 | c.784C>A p.H262N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.852); catalogued as COSV99966611; called by muse, mutect2, varscan2
- FAT3 | c.8150T>A p.I2717N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV99966613; called by muse, mutect2, varscan2
- FBN2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1561427124, COSV52518076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRL1 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839794; called by muse, mutect2, varscan2
- FCRL2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as COSV63832452; called by muse, mutect2, varscan2
- FCRL5 | c.1447C>A p.L483M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV100708980; called by muse, mutect2, varscan2
- FEN1 | c.762G>C p.K254N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV57250638; called by muse, mutect2, varscan2
- FGF23 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV52977498, COSV99426436; called by muse, mutect2, varscan2
- FGF23 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99426438; called by muse, mutect2, varscan2
- FLG | c.10166A>T p.Q3389L | Missense Mutation (SNP) | VAF 186/459 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100911618; called by muse, mutect2, varscan2
- FLNC | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368163; called by muse, mutect2, varscan2
- FMR1NB | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV100789533; called by muse, mutect2, varscan2
- FOXP2 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as COSV63486184, COSV63494364; called by muse, mutect2, varscan2
- FRG2B | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV101423524; called by muse, mutect2
- FRRS1 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99789938; called by muse, mutect2, varscan2
- FTCD | c.734C>A p.A245E | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV99385102; called by muse, mutect2, varscan2
- FUT1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100038140; called by muse, mutect2, varscan2
- FUT1 | c.278T>A p.M93K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100038142; called by muse, mutect2, varscan2
- FYTTD1 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV99611586, COSV99612072; called by muse, mutect2
- GAB3 | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as COSV100850610; called by muse, mutect2, varscan2
- GABRA2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734333, COSV62918528; called by muse, mutect2, varscan2
- GABRA6 | c.1181C>A p.A394E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV50883828, COSV99194556; called by muse, mutect2, varscan2
- GBE1 | c.533G>T p.W178L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101450162; called by muse, mutect2, varscan2
- GCC2 | c.112A>T p.M38L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100565460; called by muse, mutect2, varscan2
- GCNT1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100946560; called by muse, mutect2, varscan2
- GDI1 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100870690; called by muse, mutect2, varscan2
- GDPD4 | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100265322, COSV60018469; called by muse, mutect2, varscan2
- GHR | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as COSV100050905; called by muse, mutect2, varscan2
- GLI3 | c.1498-2A>T p.X500_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV101229892; called by muse, mutect2, varscan2
- GLI3 | c.1337C>A p.P446Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV101229893; called by muse, mutect2, varscan2
- GOT2 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 130/354 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV99803742; called by muse, mutect2
- GPR151 | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs745776872, COSV99694946; called by muse, mutect2, varscan2
- GPR155 | c.2591C>A p.P864H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99789929; called by muse, mutect2, varscan2
- GPR158 | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100893624, COSV66276134; called by muse, mutect2, varscan2
- GPR158 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100893626; called by muse, mutect2, varscan2
- GPRC5B | c.373C>G p.R125G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100315105; called by muse, mutect2, varscan2
- GRAMD1B | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs753231387, COSV100454784; called by muse, mutect2, varscan2
- GRAP2 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703007; called by muse, mutect2
- GRIA2 | c.2622C>A p.N874K | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52386476, COSV99644602; called by muse, mutect2, varscan2
- GRID1 | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV100024282; called by muse, mutect2, varscan2
- GRID2 | c.2024C>A p.T675K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as COSV56281443, COSV99941369; called by muse, mutect2, varscan2
- GRIK2 | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV100026655; called by muse, mutect2, varscan2
- GRIN2B | c.4018T>C p.F1340L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV101663055, COSV74204707; called by muse, mutect2, varscan2
- GRM5 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100552219; called by muse, mutect2, varscan2
- GRM7 | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100736753; called by muse, mutect2, varscan2
- GRM7 | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100736754; called by muse, mutect2, varscan2
- GRM8 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100283280; called by muse, mutect2, varscan2
- GUCY2D | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as COSV99644011; called by muse, mutect2, varscan2
- GZMH | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99361937; called by muse, mutect2, varscan2
- H4C12 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as rs1460975075, COSV100694791; called by muse, mutect2, varscan2
- HAL | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99701455; called by muse, varscan2
- HCN1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV100300477; called by muse, mutect2, varscan2
- HDC | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99984080; called by muse, mutect2, varscan2
- HEPACAM2 | c.677G>T p.S226I (on ENST00000394468 / NM_001039372.4; = p.S214I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100506584; called by muse, mutect2, varscan2
- HEPH | c.2857C>A p.L953I (on ENST00000343002; = p.L686I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.486); catalogued as COSV57975170; called by muse, varscan2
- HFM1 | c.3785T>A p.V1262E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99646079; called by muse, mutect2, varscan2
- HGF | c.1949T>A p.V650E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99737133; called by muse, mutect2, varscan2
- HHIP | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99667303; called by muse, mutect2, varscan2
- HHIP | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99667305; called by muse, mutect2, varscan2
- HMCN1 | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1483335148, COSV99629792; called by muse, mutect2, varscan2
- HNRNPF | c.1167C>A p.Y389* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | catalogued as rs375590998, COSV100563101, COSV61561063; called by muse, varscan2
- HNRNPF | c.1166A>T p.Y389F | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1222613734, COSV100563103; called by muse, varscan2
- HNRNPF | c.1165T>G p.Y389D | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1350872727, COSV100563104; called by muse, varscan2
- HOXB1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as rs944421558, COSV53316271; called by muse, mutect2, varscan2
- HRH3 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100420602; called by muse, mutect2, varscan2
- HRNR | c.1540T>A p.S514T | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV100913519; called by muse, mutect2, varscan2
- HS3ST1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV50027537; called by muse, mutect2, varscan2
- HSDL1 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54741318; called by muse, mutect2, varscan2
- HSPA1L | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989398; called by muse, mutect2, varscan2
- HTR4 | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.338); catalogued as COSV100088278; called by muse, mutect2, varscan2
- HTR4 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100088282; called by muse, mutect2, varscan2
- HTR5A | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.984); catalogued as COSV99839734; called by muse, mutect2, varscan2
- IARS2 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228347; called by muse, mutect2, varscan2
- IFT80 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100424782; called by muse, mutect2, varscan2
- IGFBP5 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.785); catalogued as COSV99288947; called by muse, mutect2, varscan2
- IGHV4-39 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 32/114 reads (28%) | catalogued as rs758379071; called by muse, mutect2, varscan2
- IKBIP | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100689810; called by muse, mutect2, varscan2
- IL19 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); catalogued as COSV99536330, COSV99536387; called by muse, mutect2, varscan2
- IL1B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762704392, COSV54523409; called by muse, mutect2, varscan2
- IL21R | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV100560151; called by muse, mutect2, varscan2
- IL37 | c.364T>C p.C122R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372100854; called by muse, mutect2, varscan2
- INHBA | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as rs1193620503, COSV99637016, COSV99637749; called by muse, mutect2, varscan2
- INPP4B | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53751841, COSV99524854; called by muse, mutect2, varscan2
- INSC | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV101089222; called by muse, mutect2, varscan2
- INSM2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371623805; called by muse, mutect2, varscan2
- IPO13 | c.2069A>G p.K690R | Missense Mutation (SNP) | VAF 102/374 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100961221; called by muse, mutect2, varscan2
- IQUB | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV61236746, COSV61241282; called by muse, mutect2
- IRF2BP2 | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100784325; called by muse, mutect2
- IRS2 | c.3707G>T p.G1236V | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs768224376, COSV101019126; called by muse, mutect2, varscan2
- IRS4 | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV100929569; called by muse, mutect2, varscan2
- IRX1 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100116546; called by muse, mutect2, varscan2
- ITGA1 | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99251454; called by muse, mutect2, varscan2
- ITGAX | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV99191738; called by muse, mutect2, varscan2
- ITGB4 | c.4769T>C p.L1590P | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99564088; called by muse, mutect2, varscan2
- ITGBL1 | c.465T>C p.G155= | Splice Region (SNP) | VAF 10/126 reads (8%) | catalogued as COSV101095425; called by muse, mutect2
- ITIH6 | c.2015C>G p.S672* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV99513369; called by muse, mutect2, varscan2
- ITLN1 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100406242; called by muse, mutect2, varscan2
- ITPK1 | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99968540; called by muse, mutect2, varscan2
- ITPRID1 | c.3117T>G p.D1039E | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100086506; called by muse, mutect2
- ITSN1 | c.4538A>T p.Y1513F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV101182058; called by muse, mutect2, varscan2
- JAKMIP1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101290892; called by muse, mutect2, varscan2
- KCNA2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV100315979; called by muse, mutect2, varscan2
- KCNA4 | c.1906A>C p.S636R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100068983; called by muse, mutect2, varscan2
- KCNC2 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100128911; called by muse, mutect2, varscan2
- KCNC2 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV100128922; called by muse, mutect2, varscan2
- KCNH1 | c.2410T>C p.S804P (on ENST00000271751 / NM_172362.3; = p.S777P on NM_002238.4) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99659519; called by muse, mutect2, varscan2
- KCNH2 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs555734087, COSV100060126; called by muse, mutect2, varscan2
- KCNH5 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100526701; called by muse, mutect2, varscan2
- KCNJ16 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.269); catalogued as COSV99388355; called by muse, mutect2, varscan2
- KCNQ5 | c.1745C>G p.S582* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100572125; called by muse, mutect2, varscan2
- KCTD19 | c.561C>A p.S187R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100430961; called by muse, mutect2, varscan2
- KCTD3 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99379316; called by muse, mutect2, varscan2
- KDR | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as COSV99817833; called by muse, mutect2, varscan2
- KEAP1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50297634; called by muse, mutect2, varscan2
- KIAA0586 | c.611A>T p.K204I (on ENST00000619416 / NM_001244190.2; = p.K219I on NM_014749.5) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99708201; called by muse, mutect2, varscan2
- KIAA1109 | c.12959G>T p.W4320L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV99164191; called by muse, mutect2, varscan2
- KIAA1210 | c.3808G>C p.D1270H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.391); catalogued as COSV101274180; called by muse, mutect2, varscan2
- KIF2B | c.917del p.G306Efs*63 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | catalogued as COSV52136241; called by mutect2, pindel, varscan2
- KIF2B | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99275472; called by muse, mutect2, varscan2
- KLF14 | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100205912; called by muse, mutect2
- KLK12 | c.195delinsAA p.S66Kfs*67 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as COSV99141965; called by mutect2*, pindel, varscan2*
- KLK5 | c.105T>A p.C35* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100307066; called by muse, mutect2, varscan2
- KMT2D | c.10052C>A p.S3351Y | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV56412419, COSV99982392; called by muse, mutect2, varscan2
- KRT12 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99288967; called by muse, varscan2
- KRTAP10-10 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1555936998, COSV59954305; called by muse, mutect2, varscan2
- KRTAP10-6 | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV100553779; called by muse, mutect2, varscan2
- KRTAP24-1 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100447431; called by muse, mutect2, varscan2
- KRTAP9-4 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100484899, COSV100484965; called by muse, mutect2, varscan2
- L1CAM | c.42C>G p.C14W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100649181; called by muse, mutect2, varscan2
- L3HYPDH | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99711636; called by muse, mutect2, varscan2
- L3MBTL1 | c.1728G>T p.W576C (on ENST00000418998 / NM_001377303.1; = p.W486C on NM_015478.7) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917003; called by muse, mutect2, varscan2
- LAMA1 | c.1103C>G p.T368S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056540; called by muse, mutect2
- LAMB4 | c.2428G>T p.G810W | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52718126; called by muse, mutect2, varscan2
- LAMP5 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs371250828; called by muse, mutect2, varscan2
- LBX1 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100929935; called by muse, mutect2
- LCE3D | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 78/186 reads (42%) | catalogued as rs773531645, COSV100909844; called by muse, mutect2, varscan2
- LCOR | c.3217G>T p.E1073* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99616922; called by muse, mutect2, varscan2
- LCORL | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV100481790; called by muse, mutect2, varscan2
- LCORL | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV100481794; called by muse, mutect2, varscan2
- LCT | c.1838G>A p.R613K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as COSV99929583; called by muse, mutect2, varscan2
- LIMK1 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV100283196, COSV100283204; called by muse, mutect2, varscan2
- LMAN1 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99195341; called by muse, mutect2, varscan2
- LMNTD1 | c.988C>A p.R330S | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV99279836; called by muse, mutect2, varscan2
- LPA | c.5075G>A p.R1692Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60304580; called by muse, mutect2, varscan2
- LRATD1 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99707159; called by muse, mutect2, varscan2
- LRP1B | c.13211G>C p.C4404S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV101257677, COSV67278391; called by muse, mutect2, varscan2
- LRP1B | c.9830G>T p.C3277F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101257678; called by muse, mutect2, varscan2
- LRP1B | c.2706A>T p.R902S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV63342050; called by muse, mutect2, varscan2
- LRRC15 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100752734; called by muse, mutect2, varscan2
- LRRTM2 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51220293, COSV99217803; called by muse, mutect2, varscan2
- LSM1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV100258393; called by muse, mutect2, varscan2
- LSM11 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV99643902, COSV99643968; called by muse, mutect2, varscan2
- LSM6 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99669379; called by muse, mutect2, varscan2
- LY75 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as COSV99716501; called by muse, mutect2, varscan2
- LZTS1 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV99743003; called by muse, mutect2, varscan2
- LZTS3 | c.1810G>T p.V604L (on ENST00000329152; = p.V558L on NM_001282533.2) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV53905993, COSV99417992; called by muse, mutect2, varscan2
- MAGEC2 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV99909625; called by muse, mutect2, varscan2
- MAGI2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1398598344, COSV62686212; called by muse, mutect2
- MAIP1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as COSV54461223, COSV54461564, COSV99705162; called by muse, mutect2, varscan2
- MAML2 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1233901902, COSV73262674; called by muse, mutect2, varscan2
- MAP2K3 | c.450C>G p.F150L (on ENST00000342679 / NM_145109.3; = p.F121L on NM_002756.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100383943; called by muse, mutect2, varscan2
- MAP3K20 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100169140; called by muse, mutect2, varscan2
- MAPK15 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1159344009, COSV100567906; called by muse, mutect2
- MAPK4 | c.995A>C p.D332A | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV101245533; called by muse, mutect2, varscan2
- MARCHF4 | c.980A>T p.K327M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV99814469; called by muse, mutect2, varscan2
- MAST4 | c.2782G>C p.D928H (on ENST00000403625 / NM_001164664.2; = p.D739H on NM_015183.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99844356; called by muse, mutect2, varscan2
- MCTP1 | c.1927G>T p.V643F | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.992); catalogued as COSV100387334; called by muse, mutect2, varscan2
- MECOM | c.1376C>G p.S459C (on ENST00000468789 / NM_001105078.4; = p.S647C on NM_004991.4) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs774312205, COSV99244788; called by muse, mutect2, varscan2
- MECOM | c.1226C>T p.S409L (on ENST00000468789 / NM_001105078.4; = p.S597L on NM_004991.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs745981639, COSV52959395; called by muse, mutect2, varscan2
- MED13 | c.5458A>T p.I1820F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101181105; called by muse, mutect2, varscan2
- MEDAG | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100995267; called by muse, mutect2, varscan2
- MEF2D | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs775903465, COSV100560092; called by muse, mutect2, varscan2
- MEGF10 | c.3024A>T p.K1008N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV99174990; called by muse, mutect2, varscan2
- MESP2 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV100510762; called by muse, mutect2, varscan2
- MKRN3 | c.1201A>T p.R401W | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100091166; called by muse, mutect2, varscan2
- MMP3 | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100242844; called by muse, mutect2, varscan2
- MNX1 | c.855G>A p.V285= | Splice Region (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99429662; called by muse, mutect2, varscan2
- MON1B | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99941727; called by muse, mutect2, varscan2
- MROH2B | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101270690; called by muse, mutect2, varscan2
- MRPS18B | c.355-1G>A p.X119_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99457743; called by muse, mutect2, varscan2
- MS4A1 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100619332; called by muse, mutect2, varscan2
- MS4A6A | c.210del p.F71Sfs*8 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV100124921; called by mutect2, pindel, varscan2
- MS4A7 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1386384789, COSV100279558; called by muse, mutect2, varscan2
- MSH3 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV99434022; called by muse, mutect2, varscan2
- MTBP | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100012191; called by muse, mutect2, varscan2
- MTCL1 | c.5281G>T p.G1761C (on ENST00000306329 / NM_001378206.1; = p.G1442C on NM_015210.4) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100094650; called by muse, mutect2, varscan2
- MTERF3 | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.861); catalogued as COSV99749807; called by muse, mutect2, varscan2
- MTMR4 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051065; called by muse, mutect2, varscan2
- MUC16 | c.40429C>G p.L13477V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.977); catalogued as COSV101109916; called by muse, mutect2, varscan2
- MUC16 | c.33086C>G p.S11029* | Nonsense Mutation (SNP) | VAF 45/85 reads (53%) | catalogued as COSV101200227, COSV67461137; called by muse, mutect2, varscan2
- MUC21 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 47/446 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100888875; called by muse, mutect2, varscan2
- MXRA5 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99477132; called by muse, mutect2, varscan2
- MYH7 | c.2779G>T p.E927* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as rs397516170, CM034557, COSV100806154; called by muse, mutect2, varscan2
- MYH8 | c.1267-1G>T p.X423_splice | Splice Site (SNP) | VAF 170/284 reads (60%) | catalogued as COSV101238422, COSV67961086; called by muse, mutect2, varscan2
- MYO16 | c.612T>A p.D204E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99193944; called by muse, mutect2, varscan2
- MYRIP | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56886239; called by muse, mutect2, varscan2
- NAV3 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99891495; called by muse, mutect2, varscan2
- NCF2 | c.488T>A p.M163K | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.681); catalogued as COSV100838891; called by muse, mutect2, varscan2
- NCKAP5 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100492338; called by muse, mutect2, varscan2
- NCOA6 | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100750078; called by muse, varscan2
- NDST4 | c.1674C>A p.H558Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99996609; called by muse, mutect2, varscan2
- NEB | c.8831G>T p.S2944I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99423687; called by muse, mutect2, varscan2
- NEB | c.3271G>T p.D1091Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1244163085, COSV99423696; called by muse, mutect2, varscan2
- NEIL3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220523; called by muse, mutect2, varscan2
- NEO1 | c.1632C>G p.N544K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99982143; called by muse, mutect2, varscan2
- NEUROD6 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99774060; called by muse, mutect2, varscan2
- NEUROG3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99653508; called by muse, mutect2, varscan2
- NFASC | c.1485C>A p.D495E (on ENST00000339876 / NM_001378329.1; = p.D506E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100363986, COSV100365298; called by muse, mutect2, varscan2
- NFKBIZ | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100397076; called by muse, mutect2, varscan2
- NFXL1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100216820; called by muse, mutect2, varscan2
- NID1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 29/206 reads (14%) | catalogued as rs1362510598, COSV51625910, COSV99937570; called by muse, mutect2, varscan2
- NID1 | c.1848G>T p.Q616H | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99937571; called by muse, mutect2, varscan2
- NLGN4X | c.1758A>T p.K586N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321983; called by muse, mutect2, varscan2
- NLGN4X | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99321990; called by muse, mutect2, varscan2
- NLRC5 | c.4207T>C p.C1403R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV99347408; called by muse, mutect2, varscan2
- NLRP14 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs757575343, COSV100205037; called by muse, mutect2, varscan2
- NLRP8 | c.2043-1G>C p.X681_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | catalogued as COSV99405355; called by muse, mutect2, varscan2
- NMI | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99693392; called by muse, mutect2, varscan2
- NOC3L | c.2054C>G p.A685G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100993322; called by muse, mutect2, varscan2
- NOL12 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100767148; called by muse, mutect2, varscan2
- NR1H4 | c.513C>A p.Y171* (on ENST00000551379 / NM_001206993.2; = p.Y161* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99500631; called by muse, mutect2, varscan2
- NSD1 | c.6899C>A p.A2300D | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV100729204, COSV61787960; called by muse, mutect2
- NT5DC3 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV101230971; called by muse, mutect2, varscan2
- NT5DC3 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101230972; called by muse, mutect2, varscan2
- NTM | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100868568; called by muse, mutect2, varscan2
- NUAK1 | c.710G>T p.W237L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777044; called by muse, mutect2, varscan2
- NUDT7 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99216064, COSV99216094; called by muse, mutect2, varscan2
- NUFIP2 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as rs549331208, COSV99837464; called by muse, mutect2, varscan2
- NUP188 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101001366; called by muse, mutect2, varscan2
- NXF3 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101221977; called by muse, mutect2, varscan2
- OCA2 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.049); catalogued as COSV100667970; called by muse, mutect2, varscan2
- ODF4 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV100071876; called by muse, mutect2, varscan2
- OPRL1 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.977); catalogued as COSV100402098; called by muse, mutect2, varscan2
- OR10A6 | c.369T>G p.F123L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100564293; called by muse, mutect2, varscan2
- OR10AG1 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100400095; called by muse, mutect2, varscan2
- OR10G7 | c.509C>G p.P170R | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100389947, COSV57866748; called by muse, mutect2, varscan2
- OR13F1 | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100594773; called by muse, mutect2, varscan2
- OR13G1 | c.469A>T p.T157S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV100687290; called by muse, mutect2, varscan2
- OR1J2 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.125); catalogued as COSV100093257; called by muse, mutect2
- OR1M1 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV101447561, COSV70037154; called by muse, mutect2, varscan2
- OR2L8 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100594223; called by muse, mutect2, varscan2
- OR2W3 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831695; called by muse, mutect2, varscan2
- OR3A2 | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101375058; called by muse, mutect2, varscan2
- OR4C13 | c.790_791insT p.P264Lfs*3 | Frame Shift Ins (INS) | VAF 36/167 reads (22%) | catalogued as COSV101634195; called by mutect2, pindel, varscan2
- OR4C6 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58603783; called by muse, mutect2, varscan2
- OR4C6 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs760498629, COSV100051652; called by muse, mutect2, varscan2
- OR4Q3 | c.39A>T p.Q13H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100057079; called by muse, mutect2, varscan2
- OR5AC2 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100684396, COSV62279627; called by muse, mutect2, varscan2
- OR5AC2 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100684397; called by muse, mutect2, varscan2
- OR5F1 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1411494329, COSV99558662; called by muse, mutect2, varscan2
- OR5L2 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101004328; called by muse, mutect2, varscan2
- OR5M1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV101591560; called by muse, mutect2, varscan2
- OR5T2 | c.932T>A p.M311K | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100506900, COSV100506950; called by muse, mutect2, varscan2
- OR6C3 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101110359; called by muse, mutect2, varscan2
- OR8G5 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV100422441; called by muse, mutect2, varscan2
- OR8H2 | c.738G>T p.L246F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57944325; called by muse, mutect2, varscan2
- ORC3 | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100005953; called by muse, mutect2, varscan2
- OSBPL6 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99507588; called by muse, mutect2, varscan2
- OSBPL8 | c.2203G>C p.D735H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53888924; called by muse, mutect2
- OTOF | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150834957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OXA1L | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.186); catalogued as COSV99591156; called by muse, mutect2, varscan2
- P2RY14 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99853313; called by muse, mutect2, varscan2
- PAPPA2 | c.3485A>T p.E1162V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100868224; called by muse, mutect2, varscan2
- PATE1 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99986147, COSV99986159; called by muse, mutect2
- PATL1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1439363548, COSV100274977; called by muse, mutect2, varscan2
- PAX2 | c.825C>A p.D275E (on ENST00000428433 / NM_003987.5; = p.D252E on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100695198; called by muse, mutect2, varscan2
- PAX3 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51344651; called by muse, mutect2, varscan2
- PAXBP1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV99269307; called by muse, mutect2, varscan2
- PCDH10 | c.2504T>C p.M835T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs764322733, COSV99993662; called by muse, mutect2, varscan2
- PCDH11X | c.1979C>G p.T660S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV100011995; called by muse, mutect2, varscan2
- PCDH15 | c.5282C>A p.A1761D | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV100221671; called by muse, mutect2, varscan2
- PCDHA10 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 43/70 reads (61%) | catalogued as COSV100250846, COSV56493138, COSV56555717; called by muse, mutect2, varscan2
- PCDHA3 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs142788061, COSV100793491; called by muse, mutect2, varscan2
- PCDHA5 | c.1248C>A p.S416R | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.118); catalogued as rs148202782, COSV100972303; called by muse, mutect2, varscan2
- PCDHA6 | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs782464735, COSV100972306; called by muse, mutect2, varscan2
- PCDHB1 | c.1911G>T p.M637I | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV60633108, COSV60633699; called by muse, mutect2, varscan2
- PCDHB4 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52022334, COSV52025426; called by muse, mutect2, varscan2
- PCDHB5 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV99167951; called by muse, mutect2, varscan2
- PCDHB7 | c.2081C>A p.S694* | Nonsense Mutation (SNP) | VAF 84/818 reads (10%) | catalogued as COSV50753616, COSV99177008; called by muse, mutect2
- PCDHB8 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 90/728 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); catalogued as COSV99177009; called by muse, varscan2
- PCLO | c.12142_12143insA p.L4048Hfs*3 | Frame Shift Ins (INS) | VAF 19/45 reads (42%) | catalogued as COSV100433191; called by mutect2, pindel, varscan2
- PCNX2 | c.4250A>T p.D1417V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267877; called by muse, mutect2, varscan2
- PDE1A | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114513; called by muse, mutect2, varscan2
- PDE3B | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs949148704, COSV99962636, COSV99963067; called by muse, mutect2, varscan2
- PDGFD | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs760046138, COSV56395031; called by muse, mutect2, varscan2
- PDILT | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100199452; called by muse, mutect2, varscan2
- PDP1 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892490; called by mutect2, varscan2
- PDZD4 | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99381364; called by muse, mutect2
- PDZRN3 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV99729877; called by muse, mutect2, varscan2
- PEX12 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV99862162; called by muse, mutect2
- PFKM | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV100402317, COSV100402506; called by muse, mutect2, varscan2
- PGK2 | c.367C>G p.R123G | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505513; called by muse, mutect2, varscan2
- PGM5 | c.818A>C p.Y273S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV101123457; called by muse, mutect2, varscan2
- PI15 | c.67G>T p.V23F | Missense Mutation (SNP) | VAF 208/371 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.341); catalogued as rs529529830, COSV99478046, COSV99478210; called by muse, mutect2, varscan2
- PI4KA | c.3619G>T p.D1207Y | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV99746452; called by muse, mutect2, varscan2
- PIKFYVE | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV100010811, COSV52238895; called by muse, mutect2, varscan2
- PLEKHG3 | c.2218G>T p.V740F (on ENST00000394691; = p.V796F on NM_001308147.2) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV99906644; called by muse, mutect2, varscan2
- PLEKHG4 | c.3569G>T p.C1190F | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100430960, COSV58574315; called by muse, mutect2, varscan2
- PLXDC2 | c.1027G>C p.G343R | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.373); catalogued as COSV101022989; called by muse, mutect2, varscan2
- PLXDC2 | c.1062-1G>A p.X354_splice | Splice Site (SNP) | VAF 28/46 reads (61%) | catalogued as COSV101022990; called by muse, mutect2, varscan2
- PLXNB2 | c.4871G>C p.R1624P | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1448652231, COSV100834082, COSV100834224, COSV63783405; called by muse, mutect2, varscan2
- PNMA3 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100937609; called by muse, mutect2, varscan2
- PNPLA3 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337142; called by muse, mutect2, varscan2
- PODXL | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs757945389, COSV100539493; called by muse, mutect2, varscan2
- POSTN | c.2090G>C p.G697A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.057); catalogued as COSV65714114; called by muse, mutect2, varscan2
- POSTN | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV101123343; called by muse, mutect2, varscan2
- PPARGC1A | c.568A>T p.S190C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV53533239, COSV99337980; called by muse, mutect2, varscan2
- PPME1 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs771698562, COSV100076474, COSV100076850; called by muse, mutect2, varscan2
- PPP2R2D | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101409051; called by muse, mutect2, varscan2
- PPP2R5E | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100518635; called by muse, mutect2, varscan2
- PPP6R3 | c.1468G>T p.D490Y (on ENST00000393800 / NM_001352375.2; = p.D439Y on NM_018312.5) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV99676534; called by muse, mutect2, varscan2
- PRAMEF1 | c.912C>A p.Y304* | Nonsense Mutation (SNP) | VAF 45/80 reads (56%) | catalogued as rs763300154; called by muse, mutect2, varscan2
- PRDM9 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57006567, COSV99690518; called by mutect2, varscan2
- PRR16 | c.410C>A p.P137H (on ENST00000407149 / NM_001300783.2; = p.P114H on NM_016644.2) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101087250; called by muse, mutect2, varscan2
- PRR23B | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100271968, COSV100272091; called by muse, mutect2, varscan2
- PSG9 | c.989-1G>A p.X330_splice | Splice Site (SNP) | VAF 101/185 reads (55%) | catalogued as COSV99392331; called by muse, mutect2, varscan2
- PTGR2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99966359; called by muse, mutect2, varscan2
- PTPN1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100860584; called by muse, mutect2, varscan2
- PTPRA | c.829+1G>T p.X277_splice | Splice Site (SNP) | VAF 68/142 reads (48%) | catalogued as COSV99399880; called by muse, mutect2, varscan2
- PTPRA | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV99399390, COSV99399881; called by muse, mutect2, varscan2
- PTPRB | c.3985C>A p.Q1329K | Missense Mutation (SNP) | VAF 114/227 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV54247058; called by muse, mutect2, varscan2
- PTPRE | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99617988; called by muse, mutect2, varscan2
- PTPRN2 | c.2362C>A p.L788M | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as COSV101234499; called by muse, mutect2, varscan2
- PTPRZ1 | c.304+1G>T p.X102_splice | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as COSV101100167; called by muse, mutect2, varscan2
- PTRHD1 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 59/183 reads (32%) | catalogued as COSV99579074; called by muse, mutect2, varscan2
- PXDNL | c.4248C>A p.H1416Q | Missense Mutation (SNP) | VAF 131/188 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs370461650, COSV62483245; called by muse, mutect2, varscan2
- R3HCC1L | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141521378; called by muse, mutect2, varscan2
- RAB13 | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100884089, COSV100884092; called by muse, mutect2, varscan2
- RAD18 | c.267G>T p.R89= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV53749113, COSV99368475; called by muse, mutect2, varscan2
- RAET1L | c.496A>T p.R166* | Nonsense Mutation (SNP) | VAF 90/156 reads (58%) | catalogued as COSV99657860; called by muse, varscan2
- RANBP2 | c.8660C>T p.T2887I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV99312233; called by muse, mutect2, varscan2
- RASSF6 | c.548A>G p.Y183C (on ENST00000342081 / NM_201431.2; = p.Y151C on NM_177532.5) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100274962; called by muse, mutect2, varscan2
- RBM15B | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV100082168; called by muse, mutect2, varscan2
- RELN | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633869, COSV59036527; called by muse, mutect2, varscan2
- RELN | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633870; called by muse, mutect2, varscan2
- RFX6 | c.1539C>A p.N513K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV100263779; called by muse, mutect2, varscan2
- RGS22 | c.2455-2A>G p.X819_splice | Splice Site (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100693300; called by muse, mutect2, varscan2
- RHBDL3 | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV99283644, COSV99283714; called by muse, mutect2, varscan2
- RICTOR | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99704687; called by muse, mutect2, varscan2
- RIMS2 | c.861C>A p.D287E (on ENST00000666250 / NM_001348490.2; = p.D95E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99169818; called by muse, mutect2, varscan2
- RIN2 | c.1139A>G p.Q380R (on ENST00000255006 / NM_001242581.1; = p.Q331R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99657213; called by muse, mutect2, varscan2
- RNF113A | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 226/464 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV65097429; called by muse, mutect2, varscan2
- RNF212 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1272915692, COSV100381289; called by muse, mutect2, varscan2
- RORA | c.1564G>A p.D522N (on ENST00000335670 / NM_134261.3; = p.D547N on NM_002943.3) | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as COSV99832726; called by muse, mutect2, varscan2
- RPRD2 | c.3571G>C p.E1191Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as rs1429620857, COSV100955089; called by muse, mutect2
- RSL1D1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1382624183, COSV100851987; called by muse, mutect2, varscan2
- RUSC2 | c.3249G>C p.K1083N | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100770732; called by muse, mutect2, varscan2
- RXFP1 | c.465-2A>T p.X155_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100313789; called by mutect2, varscan2
- RYR2 | c.12211G>T p.E4071* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV63670461, COSV63685976, COSV63686552; called by mutect2, varscan2
- RYR2 | c.12958G>A p.E4320K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1409819668, COSV63686403; called by muse, mutect2, varscan2
- S1PR1 | c.827T>A p.L276H | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541573; called by muse, mutect2, varscan2
- SACS | c.7804A>T p.R2602* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as COSV101207472; called by muse, mutect2, varscan2
- SAGE1 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as COSV100187356; called by muse, mutect2, varscan2
- SALL4 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs113920122, COSV99409552; called by muse, mutect2, varscan2
- SATB1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100113217, COSV58667232; called by muse, mutect2, varscan2
- SATB2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV99611400; called by muse, mutect2, varscan2
- SBK1 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs55859554, COSV100543529; called by muse, mutect2, varscan2
- SCN10A | c.5756C>A p.P1919Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047449169, COSV101479406; called by muse, mutect2, varscan2
- SCN10A | c.1333C>G p.H445D | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV101479407, COSV71861483; called by muse, mutect2, varscan2
- SCN1A | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.98); catalogued as COSV100320558; called by muse, mutect2, varscan2
- SCN4A | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101438498; called by muse, mutect2, varscan2
- SCN4A | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); catalogued as COSV101438499; called by muse, mutect2, varscan2
- SCN7A | c.4835C>T p.T1612I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV69272195; called by muse, mutect2, varscan2
- SCRIB | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100253398; called by muse, mutect2, varscan2
- SDK1 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV101269410; called by muse, mutect2, varscan2
- SDR16C5 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100373982; called by muse, mutect2, varscan2
- SEC16A | c.4704G>T p.W1568C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99258440; called by muse, mutect2, varscan2
- SERPINA7 | c.876G>C p.W292C | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59667430; called by muse, mutect2, varscan2
- SERPINF2 | c.1013A>T p.K338M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131963; called by muse, mutect2, varscan2
- SH3BP2 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100696952; called by muse, mutect2, varscan2
- SH3BP2 | c.1218G>C p.E406D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100696953; called by muse, mutect2, varscan2
- SH3RF3 | c.2618T>A p.L873H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512977; called by muse, mutect2, varscan2
- SH3TC2 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200801053, COSV100101763; called by muse, mutect2, varscan2
- SI | c.5452C>G p.L1818V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV52265831; called by muse, mutect2, varscan2
- SI | c.5052T>A p.H1684Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015699; called by muse, mutect2, varscan2
- SIDT1 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53501514, COSV99334011; called by muse, mutect2, varscan2
- SIKE1 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.905); catalogued as COSV99285282; called by muse, mutect2, varscan2
- SLC12A5 | c.2923C>A p.R975S (on ENST00000454036 / NM_001134771.2; = p.R952S on NM_020708.5) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs747552467, COSV99275635; called by muse, mutect2, varscan2
- SLC13A1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs1355119925, COSV99520978; called by muse, mutect2, varscan2
- SLC13A3 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99286699; called by muse, mutect2
- SLC14A2 | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99675548; called by muse, mutect2, varscan2
- SLC27A3 | c.575G>A p.G192D (on ENST00000271857; = p.G64D on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs371171645, COSV55163318, COSV99670249; called by muse, mutect2, varscan2
- SLC27A6 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52482555; called by muse, mutect2, varscan2
- SLC36A1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54656036; called by muse, mutect2, varscan2
- SLC6A17 | c.621C>A p.Y207* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100521329; called by muse, mutect2, varscan2
- SLC7A13 | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as COSV99878921; called by muse, mutect2, varscan2
- SLC8A3 | c.1796G>T p.R599M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as COSV99385529; called by muse, mutect2, varscan2
- SLC8B1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99176721; called by muse, mutect2
- SLCO6A1 | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101134467; called by muse, mutect2, varscan2
- SLFN11 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100390656; called by muse, mutect2, varscan2
- SLIT2 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99884155; called by muse, mutect2, varscan2
- SLIT3 | c.2009A>T p.H670L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100267933; called by muse, mutect2, varscan2
- SLITRK5 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100280798, COSV61522498; called by muse, mutect2, varscan2
- SLK | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100211782; called by muse, mutect2, varscan2
- SMARCA2 | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV100571139; called by muse, mutect2, varscan2
- SMC4 | c.3473A>G p.D1158G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100557502; called by muse, mutect2, varscan2
- SMYD3 | c.542A>T p.N181I (on ENST00000490107 / NM_001375962.1; = p.N122I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100830751; called by muse, mutect2, varscan2
- SNAP47 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as COSV100248177; called by muse, mutect2, varscan2
- SNX29 | c.1259G>T p.S420I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100028904; called by muse, mutect2, varscan2
- SOSTDC1 | c.105T>G p.H35Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV100194289; called by muse, mutect2
- SPATA17 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768969404, COSV65119275, COSV65119631, COSV65124228; called by muse, mutect2, varscan2
- SPATA6L | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV99794958; called by muse, mutect2, varscan2
- SPHKAP | c.4945A>G p.N1649D (on ENST00000392056 / NM_001142644.2; = p.N1620D on NM_030623.3) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV100764140; called by muse, mutect2, varscan2
- SPINK14 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100810975; called by muse, mutect2, varscan2
- SPNS1 | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100209095; called by muse, mutect2, varscan2
- SPTA1 | c.5533G>T p.G1845* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as COSV63748867; called by muse, mutect2, varscan2
- SPTA1 | c.2625G>T p.K875N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100935039; called by muse, mutect2, varscan2
- SPTA1 | c.738G>C p.W246C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935040; called by muse, mutect2, varscan2
- SRGAP1 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.257); catalogued as COSV100754744; called by muse, mutect2, varscan2
- SRGAP3 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100840984; called by muse, mutect2, varscan2
- SRPX | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100656093; called by muse, mutect2, varscan2
- SSTR4 | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV54798365, COSV99658592; called by muse, mutect2, varscan2
- ST8SIA3 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | PolyPhen probably damaging (0.966); catalogued as COSV100129550; called by muse, mutect2, varscan2
- STAG3 | c.2898G>C p.L966F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100425961; called by muse, mutect2, varscan2
- STAP1 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs528021678, COSV99609478; called by muse, mutect2, varscan2
- STIP1 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100534888; called by muse, mutect2, varscan2
- STOML3 | c.546G>T p.W182C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510640; called by muse, mutect2, varscan2
- STOX1 | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100057902; called by muse, mutect2, varscan2
- STX11 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845492; called by muse, mutect2, varscan2
- SYCP2 | c.3530C>A p.S1177* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100698274, COSV62770700; called by mutect2, varscan2
- SYNE3 | c.2441G>C p.G814A | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100516048; called by muse, mutect2, varscan2
- SYPL1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99163447; called by muse, mutect2, varscan2
- SZT2 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100987336; called by muse, mutect2
- TAS2R40 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV101283001; called by muse, mutect2, varscan2
- TBC1D9 | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101464346; called by muse, mutect2, varscan2
- TBX18 | c.1099+1G>T p.X367_splice | Splice Site (SNP) | VAF 65/154 reads (42%) | catalogued as COSV100858520; called by muse, mutect2, varscan2
- TCEAL3 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV99685267; called by muse, mutect2, varscan2
- TCEAL5 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs745943079, COSV101013136; called by muse, mutect2, varscan2
- TCTE3 | c.579T>A p.F193L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV100825420; called by muse, mutect2, varscan2
- TECRL | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV101168978, COSV67089885; called by muse, mutect2, varscan2
- TENM3 | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV69300075; called by muse, mutect2, varscan2
- TERF1 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99401243; called by muse, mutect2, varscan2
- TEX37 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.692); catalogued as rs151306502, COSV57555370; called by muse, mutect2
- TFAP2B | c.1082+1G>T p.X361_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | catalogued as COSV99540260; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2306T>C p.F769S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305142; called by muse, mutect2, varscan2
- TGM6 | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171801; called by muse, mutect2, varscan2
- THRAP3 | c.1554G>C p.E518D | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.717); catalogued as COSV100663406; called by muse, mutect2, varscan2
- THSD7A | c.4784T>C p.L1595P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101349178; called by muse, mutect2, varscan2
- THSD7A | c.4337G>T p.R1446I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448731; called by muse, mutect2, varscan2
- THSD7B | c.4824G>C p.M1608I (on ENST00000272643; = p.M1606I on NM_001316349.2) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99751797; called by muse, mutect2
- THY1 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52454553, COSV99411477; called by muse, mutect2, varscan2
- TIGD5 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99643484; called by muse, mutect2, varscan2
- TKTL2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761412; called by muse, mutect2, varscan2
- TLE1 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100918904, COSV64720484; called by muse, mutect2, varscan2
- TLX3 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs1217891500, COSV99740645; called by muse, mutect2
- TMC5 | c.1869G>T p.W623C (on ENST00000396229 / NM_001105248.1; = p.W377C on NM_024780.5) | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99572430, COSV99572502; called by muse, mutect2, varscan2
- TMEM119 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs972528768, COSV101219494, COSV67188514; called by muse, mutect2, varscan2
- TMEM131 | c.3968C>T p.P1323L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.122); catalogued as COSV99487866, COSV99489279; called by muse, mutect2, varscan2
- TMEM132D | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs546922206, COSV101242874, COSV67160502; called by muse, mutect2, varscan2
- TMEM159 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99238683, COSV99238686; called by muse, mutect2, varscan2
- TMEM174 | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99703779; called by muse, mutect2, varscan2
- TMEM237 | c.472A>T p.T158S (on ENST00000409883 / NM_001044385.3; = p.T150S on NM_152388.4) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99635942; called by muse, mutect2, varscan2
- TMEM63C | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs548280197, COSV100029456; called by muse, mutect2, varscan2
- TMPRSS15 | c.1553C>A p.P518Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99518036; called by muse, mutect2, varscan2
- TNC | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100405847; called by muse, mutect2, varscan2
- TNFRSF18 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.943); catalogued as COSV100148891; called by muse, mutect2, varscan2
- TNFRSF18 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.925); catalogued as COSV100148892; called by muse, mutect2, varscan2
- TNFRSF19 | c.737-1G>C p.X246_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as rs896778599, COSV99947422; called by muse, mutect2, varscan2
- TNPO1 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV100473560; called by muse, mutect2, varscan2
- TNRC6A | c.2400C>G p.C800W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100170059; called by muse, mutect2, varscan2
- TOX | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100812770; called by muse, mutect2
- TP73 | c.1004dup p.A336Cfs*31 | Frame Shift Ins (INS) | VAF 39/88 reads (44%) | catalogued as rs1465274896; called by mutect2, pindel, varscan2
- TPCN1 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100136749; called by muse, mutect2, varscan2
- TPPP3 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV99339490; called by muse, mutect2, varscan2
- TPR | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100823957; called by muse, mutect2, varscan2
- TRAPPC12 | c.1039A>T p.N347Y | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV100160573; called by muse, mutect2
- TRAPPC8 | c.3488G>T p.C1163F | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99351313; called by muse, mutect2, varscan2
- TRGC1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549223310; called by muse, mutect2, varscan2
- TRHDE | c.2694G>T p.R898S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV53835895, COSV99670998; called by muse, mutect2
- TRIM42 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV99648395; called by muse, mutect2, varscan2
- TRIM60 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV100594026; called by muse, mutect2, varscan2
- TRIM9 | c.1370G>C p.S457T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV100031473; called by muse, mutect2, varscan2
- TRIOBP | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.08); catalogued as COSV100730877; called by muse, varscan2
- TRMO | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs779678919, COSV100908877; called by muse, mutect2, varscan2
- TRPA1 | c.2924G>T p.R975M | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100084257; called by muse, mutect2, varscan2
- TRPA1 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100084258; called by muse, mutect2, varscan2
- TRPC7 | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as COSV100725733; called by muse, mutect2
- TRPV1 | c.2293G>T p.G765C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1383560593, COSV99439708; called by muse, mutect2, varscan2
- TRPV4 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.756); catalogued as COSV55681064, COSV99924748; called by muse, mutect2
- TTC27 | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV100513099; called by muse, mutect2, varscan2
- TTLL8 | c.1515C>A p.H505Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs373978372, COSV99838352; called by muse, mutect2, varscan2
- TTN | c.76964A>T p.E25655V (on ENST00000591111; = p.E18231V on NM_003319.4) | Missense Mutation (SNP) | VAF 38/174 reads (22%) | PolyPhen possibly damaging (0.876); catalogued as COSV100615100; called by muse, mutect2, varscan2
- TTN | c.48992G>T p.R16331L (on ENST00000591111; = p.R8907L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | PolyPhen possibly damaging (0.668); catalogued as COSV100615105; called by muse, mutect2
- TTN | c.39710G>T p.R13237I (on ENST00000591111; = p.R5813I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | PolyPhen probably damaging (0.931); catalogued as COSV100615109; called by muse, mutect2, varscan2
- TTN | c.17006G>T p.S5669I (on ENST00000591111; = p.S4742I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | PolyPhen possibly damaging (0.605); catalogued as COSV100615121; called by muse, mutect2, varscan2
- TXNDC16 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99909257; called by muse, mutect2, varscan2
- UBA2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875550; called by muse, mutect2, varscan2
- UBQLN3 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100293717, COSV61165767; called by muse, mutect2, varscan2
- UGGT1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.632); catalogued as COSV52137191, COSV99390769; called by muse, mutect2, varscan2
- UGT2B4 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100522442; called by muse, mutect2, varscan2
- UMOD | c.1332-1G>T p.X444_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100208396; called by muse, mutect2, varscan2
- UMODL1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV100210700; called by muse, mutect2, varscan2
- UNC13C | c.5926G>T p.A1976S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV99517961; called by muse, mutect2, varscan2
- UNC5B | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100100788; called by muse, mutect2, varscan2
- USH2A | c.2886C>G p.I962M | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100235685; called by muse, mutect2
- USP13 | c.294+2T>C p.X98_splice | Splice Site (SNP) | VAF 7/131 reads (5%) | catalogued as COSV99831204; called by muse, mutect2
- USP24 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV99599885; called by muse, mutect2, varscan2
- USP38 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100189270; called by muse, mutect2, varscan2
- USP48 | c.2625G>T p.V875= | Splice Region (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100379904; called by muse, mutect2, varscan2
- VANGL2 | c.1449G>T p.Q483H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100925577; called by muse, mutect2, varscan2
- VAX2 | c.494T>A p.L165Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as COSV99313466; called by muse, mutect2, varscan2
- VCAN | c.1226C>A p.T409K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV99425969; called by muse, mutect2, varscan2
- VCAN | c.8428A>T p.T2810S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99425972; called by muse, mutect2, varscan2
- VIT | c.1818C>A p.Y606* (on ENST00000389975 / NM_001177969.1; = p.Y621* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs773554852, COSV64900251; called by muse, mutect2, varscan2
- VOPP1 | c.152G>A p.C51Y | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1264805362, COSV99567256; called by muse, mutect2, varscan2
- VPS13B | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662161; called by muse, mutect2, varscan2
- VPS13B | c.7505-2A>T p.X2502_splice | Splice Site (SNP) | VAF 52/101 reads (51%) | catalogued as COSV100662162; called by muse, mutect2, varscan2
- VWA3B | c.1251C>A p.H417Q | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101346041; called by muse, mutect2, varscan2
- VWF | c.7359C>A p.C2453* | Nonsense Mutation (SNP) | VAF 34/60 reads (57%) | catalogued as rs775194189, COSV99779187; called by muse, mutect2, varscan2
- WDR17 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707689; called by muse, mutect2, varscan2
- WDR17 | c.1940C>G p.T647S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99707693; called by muse, mutect2, varscan2
- WWOX | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100880411; called by muse, mutect2, varscan2
- XIRP1 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100453547, COSV100453685; called by muse, mutect2, varscan2
311 further variants in this file (66 protein-altering or splice-affecting, 220 silent, 25 other) are not listed here.
